Somatic mutation profile of tumor specimen 0DSP2F from CCDI case PBCIMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (791 days).
Specimen 0DSP2F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7e59959-6e5b-4af4-ac1f-34c44ad98e1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSP2L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f086ed1b-62b1-4d45-9810-528c9e75535a

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF2 | c.5230C>T p.Q1744* | Nonsense Mutation (SNP) | VAF 42/446 reads (9%) | catalogued as rs867942606; called by muse, mutect2
- KRTAP17-1 | c.11G>T p.C4F | Missense Mutation (SNP) | VAF 54/862 reads (6%) | PolyPhen probably damaging (0.991); catalogued as COSV61972130; called by muse, mutect2
- MUC5AC | c.5687C>T p.T1896M | Missense Mutation (SNP) | VAF 115/433 reads (27%) | SIFT deleterious (0.02); catalogued as rs1211604742; called by muse, mutect2, varscan2
- SLC28A2 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs371490962; called by muse, mutect2, varscan2
- TEX2 | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 46/776 reads (6%) | catalogued as rs781841770; called by muse, mutect2
- CENPV | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 32/726 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- GJA1 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 67/623 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- RIPOR2 | c.2569+1G>A p.X857_splice | Splice Site (SNP) | VAF 68/990 reads (7%) | called by muse, mutect2
- CDS1 | c.*79A>G | 3'UTR (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
